Gene-level copy-number profile of tumor specimen C3L-07221-01 (profiled together with C3L-07221-02) from CPTAC case C3L-07221, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.9 years (22,617 days).
Specimen C3L-07221-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14dcc1c7-08a2-41f0-89cd-d165c1468325.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07221-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,783 have no estimate.
https://portal.gdc.cancer.gov/files/ca58f780-3431-44fd-b232-37347f6768c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 608; copy number 1: 8,484; copy number 2: 38,199; copy number 3: 6,196; copy number 4: 3,102; copy number 5: 954; copy number 6: 451; copy number 7: 137; copy number 8: 238; copy number 9: 42; copy number 10: 119; copy number 11: 69; copy number 12: 39; copy number 13: 65; copy number 14: 4; copy number 15: 44; copy number 16: 5; copy number 17: 12; copy number 18: 4; copy number 19: 6; copy number 21: 10; copy number 23: 11; copy number 24: 2; copy number 25: 3; copy number 27: 3; copy number 29: 5; copy number 30: 1; copy number 31: 13; copy number 49: 3; copy number 54: 7; copy number 63: 3; copy number 96: 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,933,474–98,049,863, 4 genes (within-gene range 0–1): MIR137HG, BX005019.1, MIR2682, MIR137.
- chr1:149,345,661–149,556,361, 4 genes: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr1:149,700,151–149,700,296, 1 gene (within-gene range 0–4): RNU1-68P.
- chr2:188,978,092–188,978,161, 2 genes (within-gene range 0–1): MIR1245A, MIR1245B.
- chr2:210,617,571–210,619,876, 1 gene (within-gene range 0–2): CPS1-IT1.
- chr3:1,008,135–1,012,934, 1 gene: AC087430.1.
- chr3:75,964,980–75,965,069, 1 gene (within-gene range 0–2): Y_RNA.
- chr4:74,085,995–74,099,196, 2 genes: AC093677.1, CXCL2.
- chr4:74,308,470–74,316,789, 1 gene: EPGN.
- chr4:77,350,370–77,351,235, 1 gene (within-gene range 0–1): AC008638.1.
- chr4:77,958,000–77,958,780, 1 gene: AC114801.2.
- chr4:77,987,860–78,008,688, 3 genes: HNRNPA1P56, AC114801.1, AC114801.3.
- chr4:81,030,708–81,057,627, 1 gene: BMP3.
- chr4:165,664,350–165,665,671, 1 gene: AC080079.1.
- chr4:166,918,364–166,918,478, 1 gene (within-gene range 0–1): RNA5SP171.
- chr4:171,169,209–171,169,942, 1 gene: AC092639.1.
- chr4:174,091,766–174,220,398, 3 genes: LINC02268, AC012055.1, AC012055.2.
- chr4:174,923,813–174,924,038, 1 gene (within-gene range 0–1): AC105914.1.
- chr4:175,286,605–175,290,767, 1 gene: AC095050.2.
- chr4:182,548,659–182,631,688, 2 genes (within-gene range 0–1): RNU2-34P, RN7SKP67.
- chr5:659,862–693,352, 2 genes (within-gene range 0–1): TPPP, AC026740.1.
- chr5:9,511,333–9,523,178, 2 genes (within-gene range 0–1): SEMA5A-AS1, AC027335.1.
- chr5:69,631,963–69,679,259, 3 genes: AC139495.2, GUSBP3, AC139495.1.
- chr5:135,900,353–135,954,983, 3 genes (within-gene range 0–1): AC002428.1, LECT2, FBXL21P.
- chr9:74,371,335–74,499,127, 2 genes (within-gene range 0–1): AL355674.1, RORB-AS1.
- chr10:129,768,844–130,110,830, 9 genes (within-gene range 0–1): AL157832.1, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P.
- chr10:130,962,588–131,311,721, 3 genes: MIR378C, TCERG1L, TCERG1L-AS1.
- chr10:132,508,394–132,518,367, 1 gene: AL451069.1.
- chr10:133,230,217–133,276,868, 6 genes: UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8.
- chr11:4,210,354–4,233,872, 2 genes: RDXP1, SSU72P5.
- chr14:79,199,982–79,201,632, 1 gene (within-gene range 0–1): AC022469.1.
- chr15:20,835,372–20,866,314, 2 genes: POTEB2, RNU6-749P.
- chr15:20,960,675–20,961,581, 1 gene: OR11J2P.
- chr16:32,356,981–32,380,049, 2 genes: AC133548.1, ACTR3BP3.
- chr16:32,475,051–32,615,639, 2 genes: ABCD1P3, AC137800.1.
- chr16:50,742,050–50,807,629, 4 genes: CYLD, MIR3181, AC007728.1, LINC02168.
- chr17:39,868,202–39,877,896, 1 gene: ZPBP2.
- chr18:14,613,137–14,632,806, 2 genes: OR4K8P, SNX19P3.
- chr18:33,552,123–33,578,187, 1 gene: AC091198.1.
- chr18:47,853,233–47,867,367, 2 genes (within-gene range 0–1): MTCO2P2, AC120349.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,251 genes in 132 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,913,184–121,117,257, 10 genes, copy number 6 (within-gene range 3–6): LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1.
- chr1:146,064,711–148,796,325, 78 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:149,903,318–151,953,985, 113 genes, copy number 6–9 (broad region; genes not listed).
- chr2:132,253,154–132,646,582, 12 genes, copy number 5–7 (within-gene range 3–7): RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103.
- chr2:134,231,195–135,785,056, 19 genes, copy number 5: RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1, R3HDM1, RNU6-512P, MIR128-1, UBXN4.
- chr3:169,709,295–170,418,615, 30 genes, copy number 5: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr3:172,425,850–172,821,474, 13 genes, copy number 5: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P.
- chr3:179,101,366–180,037,053, 26 genes, copy number 5–6: AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1.
- chr3:183,487,551–184,500,370, 46 genes, copy number 5 (within-gene range 5–6): KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2.
- chr3:185,076,838–186,362,234, 20 genes, copy number 5: C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG.
- chr3:186,454,969–187,180,908, 36 genes, copy number 5–7: LINC02052, LINC02051, CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L.
- chr3:193,398,967–193,844,024, 9 genes, copy number 5: ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038.
- chr3:195,959,748–196,832,647, 41 genes, copy number 5–6 (within-gene range 4–7): SDHAP1, AC024937.3, AC024937.2, TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P.
- chr3:197,645,669–198,123,232, 22 genes, copy number 6–9: AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr4:70,688,532–71,030,914, 9 genes, copy number 5: UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, RNU6-891P, MOB1B, DCK.
- chr7:57,402,181–62,275,678, 30 genes, copy number 5: AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:86,643,914–108,721,601, 479 genes, copy number 5–16 (broad region; genes not listed).
- chr7:108,909,453–113,087,778, 39 genes, copy number 5–6: AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85.
- chr7:113,415,689–119,179,149, 76 genes, copy number 5–6 (broad region; genes not listed).
- chr7:121,083,700–125,933,832, 64 genes, copy number 5–17 (broad region; genes not listed).
- chr7:126,533,665–133,170,514, 166 genes, copy number 8 (broad region; genes not listed).
- chr7:137,874,979–138,838,101, 24 genes, copy number 5–6 (within-gene range 4–7): CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213.
- chr8:73,670,441–74,208,536, 17 genes, copy number 5–8 (within-gene range 4–8): AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1.
- chr9:40,223,285–40,883,763, 20 genes, copy number 5: ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr9:62,266,319–62,534,724, 11 genes, copy number 5: AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX005266.2, BX005266.1.
- chr9:62,601,226–62,813,486, 9 genes, copy number 5–27: RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283.
- chr9:136,612,024–136,926,607, 34 genes, copy number 5–6: LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1, TRAF2, MIR4479.
- chr14:18,333,726–18,667,370, 15 genes, copy number 6–25: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12, CR383656.3.
- chr14:30,893,799–35,317,474, 78 genes, copy number 8–31 (within-gene range 1–31) (broad region; genes not listed).
- chr17:39,238,466–39,864,312, 21 genes, copy number 7–96: AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:40,792,196–41,187,136, 38 genes, copy number 13: KRT28, AC090283.1, KRT10, TMEM99, AC004231.4, KRT12, KRT20, AC004231.1, KRT23, KRT39, KRT40, KRTAP3-3, KRTAP3-2, KRTAP3-4P, KRTAP3-1, KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P.
- chr18:21,242,242–21,870,953, 18 genes, copy number 5 (within-gene range 4–6): GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2.
- chr18:21,928,985–22,348,252, 11 genes, copy number 5: RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr18:27,225,742–29,048,719, 15 genes, copy number 5–6: LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P.
- chr19:22,128,627–22,261,335, 9 genes, copy number 5: ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.1, AC073539.3.
- chr19:23,492,428–24,163,425, 22 genes, copy number 5–7: ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:87,250–1,657,779, 51 genes, copy number 5–23: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1.
- chr20:30,214,765–37,097,178, 227 genes, copy number 5–7 (broad region; genes not listed).
- chr21:7,744,962–9,129,752, 42 genes, copy number 6: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,122,273–13,120,807, 18 genes, copy number 5–13: CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 6,280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
